Somatic mutation profile of tumor specimen TCGA-S7-A7X2-01A (aliquot TCGA-S7-A7X2-01A-12D-A35I-08) from TCGA case TCGA-S7-A7X2, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 57.6 years (21,054 days).
Specimen TCGA-S7-A7X2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f04912d9-1244-4874-bfc8-2185c8615729.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S7-A7X2-10A (Blood Derived Normal), aliquot TCGA-S7-A7X2-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3f836cd-3a2f-4708-aa54-0dcf35d6ab56

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Nonstop Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM187B | c.195C>G p.S65R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.141); called by mutect2, varscan2
- FMOD | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- IL4R | c.2305G>T p.V769F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- LPCAT3 | c.1464A>C p.*488Yext*98 | Nonstop Mutation (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- TECRL | c.382T>C p.S128P | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- TNFAIP1 | c.808_820del p.T270Afs*78 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- LRP1 | c.8775C>T p.N2925= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs139174222; called by muse, mutect2, varscan2
- POLN | c.1959A>G p.V653= | Silent (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- SLC17A6 | c.1101A>G p.G367= | Silent (SNP) | VAF 48/177 reads (27%) | called by muse, mutect2, varscan2
